Somatic mutation profile of tumor specimen C3L-02629-01 (aliquot CPT0202170006) from CPTAC case C3L-02629, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 57.9 years (21,143 days).
Specimen C3L-02629-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ebe14127-7683-4a15-8e8e-f988cd2787c6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02629-31 (Blood Derived Normal), aliquot CPT0202330002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dd50a70f-7517-4343-b384-a0189c673774

The open-access MAF lists 92 somatic variants for this specimen: 64 protein-altering or splice-affecting, 19 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 19, Nonsense Mutation 7, Intron 2, 5'UTR 2, RNA 2, 3'UTR 2, Splice Region 2, 5'Flank 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.2313_2324dup p.Y772_A775dup | In Frame Ins (INS) | VAF 37/161 reads (23%) | hotspot (GDC flag); catalogued as rs397516975; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- TP53 | c.839G>A p.R280K | Missense Mutation (SNP) | VAF 34/584 reads (6%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as rs121912660, CM153865, CM993218, COSV52666248, COSV52677783, COSV52687987; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2
- C4orf54 | c.2857G>A p.E953K | Missense Mutation (SNP) | VAF 16/240 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.807); catalogued as rs747939393, COSV72766762; called by muse, mutect2
- COL3A1 | c.1345C>A p.R449S | Missense Mutation (SNP) | VAF 25/306 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.2); catalogued as COSV58595248; called by muse, mutect2
- COL6A3 | c.9130G>A p.V3044I | Missense Mutation (SNP) | VAF 19/242 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs374628435; ClinVar: uncertain significance; called by muse, mutect2
- DNAH3 | c.11797C>A p.P3933T | Missense Mutation (SNP) | VAF 16/350 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99765480; called by muse, mutect2
- MBTPS1 | c.2500C>T p.P834S | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as COSV58572548; called by muse, mutect2
- OR4C15 | c.622C>T p.H208Y (on ENST00000314644; = p.H154Y on NM_001001920.2) | Missense Mutation (SNP) | VAF 15/166 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.935); catalogued as rs760005853; called by muse, mutect2
- PEAR1 | c.2431C>A p.P811T | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.63); catalogued as COSV52772690; called by muse, mutect2, varscan2
- PYROXD2 | c.399G>T p.R133S | Missense Mutation (SNP) | VAF 14/191 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV65330417; called by muse, mutect2
- TNXB | c.3625G>A p.E1209K (on ENST00000647633; = p.E962K on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/264 reads (5%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.941); catalogued as COSV64480527; called by muse, mutect2
- TP53 | c.442G>C p.D148H | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.544); catalogued as COSV52713626, COSV52853816, COSV53387316, COSV53697288; called by muse, mutect2
- TWIST1 | c.563C>A p.S188* | Nonsense Mutation (SNP) | VAF 24/236 reads (10%) | catalogued as CM072098; called by muse, mutect2, varscan2
- ABI3 | c.754G>T p.V252L | Missense Mutation (SNP) | VAF 12/179 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2
- ADAMTS6 | c.2485C>G p.P829A | Missense Mutation (SNP) | VAF 16/181 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2
- ANK1 | c.224C>A p.T75N | Missense Mutation (SNP) | VAF 24/378 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.345); called by muse, mutect2
- AP1M2 | c.42+3G>A | Splice Region (SNP) | VAF 14/263 reads (5%) | called by muse, mutect2
- BBS10 | c.1411G>A p.D471N | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.006); called by muse, mutect2
- BRPF1 | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 10/214 reads (5%) | SIFT tolerated (0.69); PolyPhen benign (0.007); called by muse, mutect2
- CACNA1S | c.921T>G p.N307K | Missense Mutation (SNP) | VAF 17/287 reads (6%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.665); called by muse, mutect2
- CCDC40 | c.3316C>G p.L1106V | Missense Mutation (SNP) | VAF 36/470 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- CDHR5 | c.2288G>A p.G763E (on ENST00000358353 / NM_001171968.2; = p.G769E on NM_021924.5) | Missense Mutation (SNP) | VAF 9/171 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.015); called by muse, mutect2
- CGNL1 | c.1294C>T p.Q432* | Nonsense Mutation (SNP) | VAF 32/410 reads (8%) | called by muse, mutect2
- CHD2 | c.1528G>A p.E510K | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- CMTR2 | c.1955C>T p.T652I | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CNR2 | c.145C>G p.L49V | Missense Mutation (SNP) | VAF 11/249 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- DDI1 | c.770C>G p.A257G | Missense Mutation (SNP) | VAF 10/233 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DMXL1 | c.653A>C p.Q218P | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2
- DTHD1 | c.2246G>T p.R749L (on ENST00000456874; = p.R584L on NM_001136536.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.736); called by muse, mutect2
- EFR3B | c.173C>G p.S58C | Missense Mutation (SNP) | VAF 7/201 reads (3%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); called by muse, mutect2
- ERICH4 | c.271G>C p.E91Q | Missense Mutation (SNP) | VAF 12/214 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- FBN2 | c.3112G>C p.E1038Q | Missense Mutation (SNP) | VAF 18/586 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.021); called by muse, mutect2
- FLT1 | c.1046G>T p.G349V | Missense Mutation (SNP) | VAF 14/384 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FSIP2 | c.12057T>A p.N4019K | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- GATM | c.1045C>T p.H349Y | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- GLI2 | c.2140C>A p.Q714K (on ENST00000361492 / NM_001374353.1; = p.Q731K on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/229 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); called by muse, mutect2
- HERPUD1 | c.1021G>C p.D341H | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); called by muse, mutect2
- HOXD3 | c.717G>C p.K239N | Missense Mutation (SNP) | VAF 22/313 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- IMPG2 | c.1126G>C p.D376H | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- JADE1 | c.1047G>T p.M349I | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LENG8 | c.475C>A p.Q159K | Missense Mutation (SNP) | VAF 20/196 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.366); called by muse, mutect2
- MCM10 | c.1263G>C p.K421N (on ENST00000484800 / NM_182751.3; = p.K420N on NM_018518.5) | Missense Mutation (SNP) | VAF 29/380 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.353); called by muse, mutect2
- MRC2 | c.2269C>T p.Q757* | Nonsense Mutation (SNP) | VAF 12/197 reads (6%) | called by muse, mutect2
- MYO9B | c.1950G>C p.K650N | Missense Mutation (SNP) | VAF 15/249 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR2T2 | c.443G>C p.G148A | Missense Mutation (SNP) | VAF 20/540 reads (4%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.469); called by muse, mutect2
- OR5L1 | c.358T>A p.Y120N | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCDHGC4 | c.385C>T p.H129Y | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.406); called by muse, mutect2
- PLOD1 | c.385G>T p.E129* | Nonsense Mutation (SNP) | VAF 7/194 reads (4%) | called by muse, mutect2
- RNPC3 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.972); called by muse, varscan2
- SARS2 | c.963-4C>A | Splice Region (SNP) | VAF 45/746 reads (6%) | called by muse, mutect2
- SLAMF1 | c.280G>T p.D94Y | Missense Mutation (SNP) | VAF 24/260 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.804); called by muse, mutect2
- SLC5A6 | c.355C>T p.P119S | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- SPAG5 | c.41C>T p.S14L | Missense Mutation (SNP) | VAF 15/357 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SPATA18 | c.1312G>A p.D438N | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- SPTBN4 | c.6496G>A p.D2166N | Missense Mutation (SNP) | VAF 17/238 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.175); called by muse, mutect2
- SS18 | c.331G>A p.G111S | Missense Mutation (SNP) | VAF 18/292 reads (6%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.01); called by muse, mutect2
- SYNRG | c.2269G>T p.G757* | Nonsense Mutation (SNP) | VAF 10/232 reads (4%) | called by muse, mutect2
- TG | c.7345G>T p.E2449* | Nonsense Mutation (SNP) | VAF 42/576 reads (7%) | called by muse, mutect2
- TMEM219 | c.710G>A p.R237K | Missense Mutation (SNP) | VAF 20/236 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.047); called by muse, mutect2
- TRIM42 | c.1755G>C p.Q585H | Missense Mutation (SNP) | VAF 17/297 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2
- TTC9 | c.471G>T p.L157F | Missense Mutation (SNP) | VAF 16/220 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- VHL | c.61G>T p.E21* | Nonsense Mutation (SNP) | VAF 7/137 reads (5%) | called by muse, mutect2
- XYLT1 | c.99G>T p.W33C | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- ZNF14 | c.958G>A p.A320T | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0); called by mutect2, varscan2
- BMPER | c.240G>A p.K80= | Silent (SNP) | VAF 23/417 reads (6%) | catalogued as rs775250760, COSV51814997; called by muse, mutect2
- C8orf82 | c.462G>A p.L154= | Silent (SNP) | VAF 8/98 reads (8%) | catalogued as rs1207703755; called by muse, mutect2
- CORO1B | c.357C>T p.S119= | Silent (SNP) | VAF 26/217 reads (12%) | catalogued as rs1164482437; called by muse, mutect2, varscan2
- CPT1B | c.1761G>C p.L587= | Silent (SNP) | VAF 22/240 reads (9%) | called by muse, mutect2
- CSMD1 | c.3571C>T p.L1191= (on ENST00000520002; = p.L1190= on NM_033225.6) | Silent (SNP) | VAF 11/111 reads (10%) | catalogued as rs1563291665; called by muse, mutect2
- DENND6A | c.40C>A p.R14= | Silent (SNP) | VAF 18/238 reads (8%) | called by muse, mutect2
- EDNRA | c.1182G>T p.L394= | Silent (SNP) | VAF 10/158 reads (6%) | catalogued as COSV60096510; called by muse, mutect2
- FN1 | c.5508C>T p.T1836= | Silent (SNP) | VAF 15/340 reads (4%) | called by muse, mutect2
- LIG1 | c.2283G>A p.V761= | Silent (SNP) | VAF 6/91 reads (7%) | called by muse, mutect2
- MACF1 | c.18270T>A p.A6090= (on ENST00000372915; = p.A4135= on NM_012090.5) | Silent (SNP) | VAF 8/78 reads (10%) | called by muse, mutect2, varscan2
- MAP6 | c.1599C>A p.V533= | Silent (SNP) | VAF 33/259 reads (13%) | called by muse, mutect2, varscan2
- OR1L8 | c.66T>A p.P22= | Silent (SNP) | VAF 6/102 reads (6%) | called by muse, mutect2
- PIGG | c.855G>A p.V285= | Silent (SNP) | VAF 16/216 reads (7%) | called by muse, mutect2
- RNF213 | c.7794C>G p.V2598= | Silent (SNP) | VAF 16/300 reads (5%) | called by muse, mutect2
- RTEL1 | c.729G>A p.K243= | Silent (SNP) | VAF 24/361 reads (7%) | catalogued as rs972714667; called by muse, mutect2
- SHLD2 | c.426C>T p.L142= | Silent (SNP) | VAF 7/54 reads (13%) | called by muse, mutect2, varscan2
- TP53 | c.837G>A p.G279= | Silent (SNP) | VAF 34/572 reads (6%) | catalogued as rs786201322, CD963012, COSV53098982, COSV53696473; ClinVar: likely benign; called by muse, mutect2
- ZGRF1 | c.2487A>G p.L829= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV100005799; called by mutect2, varscan2
- ZNF326 | c.309C>T p.F103= | Silent (SNP) | VAF 13/203 reads (6%) | catalogued as rs1468309869; called by muse, mutect2
- ADAM21P1 | n.1065C>G | RNA (SNP) | VAF 26/384 reads (7%) | called by muse, mutect2
- CTTN | c.*557C>T | 3'UTR (SNP) | VAF 73/528 reads (14%) | called by muse, mutect2, varscan2
- DAO | chr12:108879620 G>A | 5'Flank (SNP) | VAF 13/121 reads (11%) | catalogued as rs190339460; called by muse, mutect2, varscan2
- KCNG4 | c.*2T>A | 3'UTR (SNP) | VAF 6/76 reads (8%) | called by muse, mutect2
- KIR2DL3 | c.-32G>T | 5'UTR (SNP) | VAF 29/461 reads (6%) | called by muse, mutect2
- MARCHF1 | c.163-99C>A | Intron (SNP) | VAF 9/47 reads (19%) | called by muse, varscan2
- SSPOP | n.1968C>T | RNA (SNP) | VAF 27/298 reads (9%) | called by muse, mutect2
- TP53 | c.993+262G>T | Intron (SNP) | VAF 10/133 reads (8%) | called by muse, mutect2
- ZPBP | c.-28A>T | 5'UTR (SNP) | VAF 33/307 reads (11%) | called by muse, mutect2, varscan2
